TCGA case TCGA-EJ-5494 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e27c50e2-2a41-4f8c-9ef8-2bc51fb0c23e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.9 years (18,596 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC clinical T: T2a; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason grade tertiary: Pattern 4; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 17; Tumor level prostate: Apex / Middle.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 826 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,477 days (4.0 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EJ-5494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-EJ-5494-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 18; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-EJ-5494-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 18; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EJ-5494-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EJ-5494-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined: Yes; Biochemical recurrence indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Stage record, Psa: Days to PSA most recent: 184.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3; Gleason pattern tertiary: 4.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,477 days; disease-specific survival: no event (censored), 1,477 days; disease-free interval: no event (censored), 1,477 days; progression-free interval: no event (censored), 1,477 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EJ-5494-01A-01D-1574-01): tumor purity 0.74, ploidy 2, whole-genome doublings 0.
